Somatic mutation profile of tumor specimen C3N-03913-02 (aliquot CPT0222900006) from CPTAC case C3N-03913, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 45.3 years (16,533 days).
Specimen C3N-03913-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Shoulder; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb53f04d-fc74-45f9-86ca-b562a5920cb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03913-71 (Blood Derived Normal), aliquot CPT0223010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa96afb4-4e94-4cf2-a215-dfe9e315eedc

The open-access MAF lists 680 somatic variants for this specimen: 439 protein-altering or splice-affecting, 215 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 394, Silent 215, Nonsense Mutation 28, Intron 16, Splice Region 6, 3'UTR 4, Splice Site 3, 5'UTR 3, 3'Flank 3, Frame Shift Ins 3, Frame Shift Del 2, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG8 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 72/214 reads (34%) | catalogued as rs200888240, COSV100219986, COSV55203161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANOS1 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 209/511 reads (41%) | catalogued as rs137852516, CM021282, COSV52920162; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 64/210 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GBA | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 165/546 reads (30%) | catalogued as rs121908309, CM940811, CX165705, COSV59169115; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 217/329 reads (66%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.2729C>T p.S910L | Missense Mutation (SNP) | VAF 126/299 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs199473175, CM024643, COSV100347038; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- VWF | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 177/373 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs61753997, CM001811; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1888G>A p.E630K (on ENST00000404938 / NM_001163941.2; = p.E185K on NM_178559.6) | Missense Mutation (SNP) | VAF 172/296 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV51722530; called by muse, mutect2, varscan2
- AC132217.2 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 112/329 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as rs1304549931, COSV56097132; called by muse, mutect2, varscan2
- ADA | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 183/438 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1294381082, COSV100866645, COSV65739954; called by muse, mutect2, varscan2
- ADAM30 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 155/334 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs781229975, COSV65560969; called by muse, mutect2, varscan2
- ADAMTS20 | c.940C>T p.H314Y | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as rs1447212716; called by muse, mutect2, varscan2
- ADCY7 | c.3038G>A p.G1013E | Missense Mutation (SNP) | VAF 113/244 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745575984; called by muse, mutect2, varscan2
- AHDC1 | c.3331C>T p.R1111W | Missense Mutation (SNP) | VAF 92/373 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1018122413, COSV55939306; called by muse, varscan2
- AKT2 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 179/392 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs751752149; called by muse, mutect2, varscan2
- ALDH3B1 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 83/323 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs563089229; called by muse, mutect2, varscan2
- ALK | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV66595468; called by muse, mutect2, varscan2
- ANKFN1 | c.3760G>A p.E1254K (on ENST00000653862; = p.E1107K on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/301 reads (29%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.065); catalogued as rs772128737; called by muse, mutect2, varscan2
- ANKRD31 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 63/206 reads (31%) | catalogued as rs533916008; called by muse, mutect2, varscan2
- APOB | c.4162C>T p.R1388C | Missense Mutation (SNP) | VAF 86/299 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as rs267599185, COSV51928488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARFGEF3 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 85/239 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs772700641; called by muse, mutect2, varscan2
- ARHGEF26 | c.2126G>A p.R709K | Missense Mutation (SNP) | VAF 128/206 reads (62%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100726549, COSV62846047; called by muse, mutect2, varscan2
- ASTN1 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 178/301 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs1424858081, COSV56073783; called by muse, mutect2, varscan2
- ASXL3 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 139/232 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52463987; called by muse, mutect2, varscan2
- ATP7B | c.2411C>T p.T804I | Missense Mutation (SNP) | VAF 141/414 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.7); catalogued as rs1201914441; called by muse, mutect2, varscan2
- B3GALT1 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 90/256 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.633); catalogued as rs1340830027; called by muse, mutect2, varscan2
- BAZ2B | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 61/194 reads (31%) | catalogued as rs780189423, COSV58596651, COSV58605383; called by muse, mutect2, varscan2
- BRAF | c.1914_1915insGTT p.A638_T639insV (on ENST00000288602 / NM_001374244.1; = p.A598_T599insV on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Ins (INS) | VAF 122/225 reads (54%) | catalogued as COSV56086959, COSV56201191; called by mutect2, pindel, varscan2
- BTBD11 | c.2196G>A p.M732I (on ENST00000280758 / NM_001018072.2; = p.M269I on NM_001017523.2) | Missense Mutation (SNP) | VAF 57/272 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV55019873; called by muse, mutect2, varscan2
- C12orf50 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs776851924, COSV53893621; called by muse, mutect2, varscan2
- C1QTNF9 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 175/280 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100129803; called by muse, mutect2, varscan2
- C1orf94 | c.1609C>T p.Q537* (on ENST00000488417 / NM_001134734.2; = p.Q347* on NM_032884.5) | Nonsense Mutation (SNP) | VAF 150/326 reads (46%) | catalogued as COSV64915029; called by muse, mutect2, varscan2
- C7 | c.1027C>T p.H343Y | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.154); catalogued as COSV100496622; called by muse, mutect2, varscan2
- CACNA1H | c.5822C>T p.S1941L | Missense Mutation (SNP) | VAF 105/506 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs1291910282, COSV99326350; called by muse, mutect2, varscan2
- CATSPERD | c.1661G>A p.G554E | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.796); catalogued as rs771955783; called by muse, mutect2, varscan2
- CBLL2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 170/490 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.107); catalogued as rs908529189, COSV100081687, COSV60368760; called by muse, mutect2, varscan2
- CCDC144A | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV60698465; called by muse, mutect2, varscan2
- CCDC85A | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs765502186, COSV101339350, COSV68149842; called by muse, mutect2, varscan2
- CCER1 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 237/527 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as rs1412453346; called by muse, mutect2, varscan2
- CCR6 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 123/322 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59475261; called by muse, mutect2, varscan2
- CCT8L2 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 178/492 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV63463437; called by muse, mutect2, varscan2
- CD300LG | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 88/206 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1243588085; called by muse, varscan2
- CDH18 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56903848; called by muse, mutect2, varscan2
- CDH20 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 158/255 reads (62%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as rs1219644308; called by muse, mutect2, varscan2
- CENPE | c.1670C>T p.S557L | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1287350091, COSV54392180; called by muse, mutect2, varscan2
- CFAP54 | c.4804G>A p.D1602N | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.422); catalogued as rs143758581; called by muse, mutect2, varscan2
- CLU | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 102/253 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs1168833638; called by muse, mutect2, varscan2
- CMYA5 | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 70/248 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV71407677; called by muse, mutect2, varscan2
- COL12A1 | c.5335C>T p.R1779C | Missense Mutation (SNP) | VAF 102/277 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs760210784; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A3 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 100/474 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs367847974; called by muse, mutect2, varscan2
- COL6A2 | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 118/340 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs929008624; called by muse, mutect2, varscan2
- COL7A1 | c.4566G>A p.G1522= | Splice Region (SNP) | VAF 84/360 reads (23%) | catalogued as COSV60394618; called by muse, mutect2, varscan2
- CPHXL | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs1382091925, COSV73691849; called by muse, mutect2, varscan2
- CPM | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58033053; called by muse, mutect2, varscan2
- CRACD | c.2114C>T p.S705F | Missense Mutation (SNP) | VAF 157/354 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs371038521, COSV51719680; called by muse, mutect2, varscan2
- CSMD1 | c.1124C>T p.S375L (on ENST00000520002; = p.S374L on NM_033225.6) | Missense Mutation (SNP) | VAF 87/229 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs762593887, COSV68165271; called by muse, varscan2
- CSMD2 | c.2471G>A p.G824E | Missense Mutation (SNP) | VAF 146/340 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261489927; called by muse, mutect2, varscan2
- CT47B1 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 200/571 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs746347112, COSV64890480; called by muse, mutect2, varscan2
- CTAGE6 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 259/1166 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs747073118, COSV69917275; called by muse, mutect2, varscan2
- CYFIP2 | c.2288C>T p.P763L (on ENST00000616178 / NM_001291722.2; = p.P738L on NM_014376.4) | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.105); catalogued as rs367713994; called by muse, mutect2, varscan2
- CYLC2 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 78/291 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as rs865905715; called by muse, mutect2, varscan2
- CYP4F11 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 63/302 reads (21%) | catalogued as COSV56125785; called by muse, mutect2, varscan2
- CYP4F3 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV55407465; called by muse, mutect2, varscan2
- CYSLTR1 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 177/443 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100964704; called by muse, mutect2, varscan2
- DNAH11 | c.4831G>A p.E1611K | Missense Mutation (SNP) | VAF 72/434 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV60981117; called by muse, mutect2
- DNAH12 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 128/266 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1006370903, COSV60855640, COSV60856070; called by muse, mutect2, varscan2
- DNAH5 | c.13492G>A p.E4498K | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54204981; called by muse, mutect2, varscan2
- DNAH5 | c.10948G>A p.E3650K | Missense Mutation (SNP) | VAF 73/248 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs371447360; called by muse, mutect2, varscan2
- DNAJC5G | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV56081323; called by muse, mutect2, varscan2
- DOCK10 | c.2853C>T p.F951= | Splice Region (SNP) | VAF 44/144 reads (31%) | catalogued as rs372046210; called by muse, mutect2, varscan2
- DXO | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 277/1055 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV61713364; called by muse, mutect2, varscan2
- EP300 | c.3115C>T p.P1039S | Missense Mutation (SNP) | VAF 141/347 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.725); catalogued as COSV54326791; called by muse, mutect2, varscan2
- F8 | c.1537G>A p.G513S | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1269117966, CM020115; called by muse, mutect2, varscan2
- FAM126A | c.812T>C p.L271S | Missense Mutation (SNP) | VAF 179/271 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101327104; called by muse, mutect2, varscan2
- FAM236C | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 97/482 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1274426882; called by muse, mutect2, varscan2
- FAM3D | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 138/306 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs149077834; called by muse, varscan2
- FARP2 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 34/132 reads (26%) | catalogued as rs766813957; called by muse, mutect2, varscan2
- FASLG | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 74/417 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60679817; called by muse, mutect2, varscan2
- FBXO7 | c.1289A>T p.H430L | Missense Mutation (SNP) | VAF 192/537 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.055); catalogued as COSV56681841; called by muse, mutect2, varscan2
- FCGRT | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 182/428 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs758671395, COSV54541247; called by muse, mutect2, varscan2
- FHIT | c.351C>T p.L117= | Splice Region (SNP) | VAF 52/218 reads (24%) | catalogued as rs1405239812; called by muse, mutect2, varscan2
- FOXA3 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 127/544 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100141538; called by muse, mutect2, varscan2
- FRS2 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 143/288 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as rs550828203, COSV54725428; called by muse, mutect2, varscan2
- GABRA1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV104376867, COSV99195746; called by muse, mutect2, varscan2
- GALP | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1231510083; called by muse, mutect2, varscan2
- GATA3 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 270/423 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as CM1211211; called by muse, mutect2, varscan2
- GIMAP8 | c.1455C>G p.D485E | Missense Mutation (SNP) | VAF 76/530 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV56230221; called by muse, mutect2, varscan2
- GJA5 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 92/577 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150906806; called by muse, mutect2, varscan2
- GLI3 | c.4291C>T p.P1431S | Missense Mutation (SNP) | VAF 331/508 reads (65%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as COSV67895352; called by muse, mutect2, varscan2
- GLIS3 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 159/244 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1264261637, COSV100173705; called by muse, mutect2, varscan2
- GPC5 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 111/301 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as rs771156014; called by muse, mutect2, varscan2
- GPX6 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 90/813 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs761607451, COSV62659438; called by muse, mutect2, varscan2
- GRIN3A | c.2482G>A p.G828R | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866984142, COSV62456022; called by muse, mutect2, varscan2
- GRIP1 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 73/323 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.813); catalogued as rs1308604328, COSV54024909; called by muse, mutect2, varscan2
- GRIP2 | c.1207G>A p.E403K (on ENST00000619221; = p.E306K on NM_001080423.4) | Missense Mutation (SNP) | VAF 134/317 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); catalogued as COSV56119812, COSV56121348; called by muse, mutect2, varscan2
- GTF3C4 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV104427267; called by muse, mutect2, varscan2
- HCN1 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.223); catalogued as COSV57536540; called by muse, mutect2, varscan2
- HCRTR2 | c.1159C>T p.H387Y | Missense Mutation (SNP) | VAF 96/264 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0.157); catalogued as rs1396999335; called by muse, mutect2, varscan2
- HMGCLL1 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51442355; called by muse, mutect2, varscan2
- HNRNPCL2 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 77/272 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV60403192; called by muse, mutect2, varscan2
- HYDIN | c.7639G>A p.D2547N | Missense Mutation (SNP) | VAF 88/440 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.131); catalogued as rs757454825; called by muse, varscan2
- IGF2BP1 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 98/265 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs987788624; called by muse, mutect2, varscan2
- IGKV1-39 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.433); catalogued as rs1438490158; called by muse, mutect2, varscan2
- IL18RAP | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs751995622; called by muse, mutect2, varscan2
- INPP5J | c.1272G>A p.R424= (on ENST00000331075 / NM_001284285.2; = p.R56= on NM_001002837.2) | Splice Region (SNP) | VAF 106/278 reads (38%) | catalogued as COSV58513959; called by muse, mutect2, varscan2
- IPO4 | c.2338C>T p.R780C | Missense Mutation (SNP) | VAF 94/402 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs201767926; called by muse, mutect2, varscan2
- IQCB1 | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 173/252 reads (69%) | catalogued as COSV60439021; called by muse, mutect2, varscan2
- KCNB2 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 89/239 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.96); catalogued as COSV73049036; called by muse, mutect2, varscan2
- KIAA1671 | c.5308C>T p.R1770C | Missense Mutation (SNP) | VAF 186/530 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1429360488; called by muse, mutect2, varscan2
- KLRC1 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.162); catalogued as rs1301855382; called by muse, mutect2, varscan2
- KRT72 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 138/285 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs766532753, COSV53373404; called by muse, mutect2, varscan2
- LMAN2 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 84/259 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1217008351; called by muse, mutect2, varscan2
- LMOD3 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV70456016; called by muse, mutect2, varscan2
- LPA | c.4333C>T p.R1445C | Missense Mutation (SNP) | VAF 78/193 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs778266525, COSV60300378; called by muse, varscan2
- LRIT1 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 160/274 reads (58%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV64512192, COSV64513765; called by muse, varscan2
- LRP1B | c.10087C>T p.Q3363* | Nonsense Mutation (SNP) | VAF 60/165 reads (36%) | catalogued as COSV67273422; called by muse, mutect2, varscan2
- LRP1B | c.9603G>A p.M3201I | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV101259967, COSV67279430; called by muse, mutect2, varscan2
- LRRC15 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 32/329 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs781238952; called by muse, mutect2, varscan2
- LRRC7 | c.3704G>A p.R1235K (on ENST00000651989 / NM_001370785.2; = p.R1202K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50413693, COSV99230483; called by muse, mutect2, varscan2
- MAMLD1 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 252/687 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781975575; called by muse, mutect2, varscan2
- MDN1 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs747796527, COSV104428634; called by muse, mutect2, varscan2
- METAP1 | c.901C>T p.H301Y | Missense Mutation (SNP) | VAF 140/297 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56443410; called by muse, mutect2, varscan2
- MGAM | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 47/357 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs781807541; called by muse, mutect2, varscan2
- MLC1 | c.1103G>A p.W368* | Nonsense Mutation (SNP) | VAF 156/456 reads (34%) | catalogued as COSV61118124; called by muse, mutect2, varscan2
- MLLT6 | c.2285C>T p.P762L | Missense Mutation (SNP) | VAF 307/642 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1295714586; called by muse, mutect2, varscan2
- MTA1 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 83/317 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs868920310, COSV58756428; called by muse, mutect2, varscan2
- MUC16 | c.23212C>T p.P7738S | Missense Mutation (SNP) | VAF 76/310 reads (25%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.076); catalogued as rs945051343; called by muse, mutect2, varscan2
- MUC4 | c.5572C>T p.P1858S | Missense Mutation (SNP) | VAF 187/1133 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.65); catalogued as rs572164796; called by muse, mutect2, varscan2
- MUC5B | c.2174C>T p.S725F | Missense Mutation (SNP) | VAF 128/367 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs1265536847, COSV71594426; called by muse, mutect2, varscan2
- MYBPC1 | c.1996T>A p.W666R (on ENST00000550270 / NM_206820.2; = p.W691R on NM_002465.4) | Missense Mutation (SNP) | VAF 62/295 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100637860; called by muse, mutect2, varscan2
- MYO3A | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 70/115 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs754917866; called by muse, mutect2, varscan2
- MYRIP | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 66/255 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs772207839, COSV56868067; called by muse, mutect2, varscan2
- MZT2B | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 122/382 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs138130291; called by muse, mutect2
- NALCN | c.4619G>A p.R1540Q | Missense Mutation (SNP) | VAF 59/314 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99216742; called by muse, mutect2, varscan2
- NBEA | c.1493G>A p.G498E | Missense Mutation (SNP) | VAF 123/330 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1172167511, COSV59787830; called by muse, mutect2, varscan2
- NDST3 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 72/349 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.964); catalogued as COSV56619282; called by muse, mutect2, varscan2
- NEUROD4 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 200/397 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.36); catalogued as rs1241017522, COSV54472486, COSV54473978; called by muse, mutect2, varscan2
- NEXMIF | c.4345C>T p.R1449C | Missense Mutation (SNP) | VAF 188/453 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs946737858, COSV50075185; called by muse, mutect2, varscan2
- NLRP13 | c.2317G>A p.D773N | Missense Mutation (SNP) | VAF 68/304 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.042); catalogued as COSV61620306; called by muse, mutect2, varscan2
- NPAP1 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 146/462 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.134); catalogued as COSV61505829; called by muse, varscan2
- NPAP1 | c.2525C>T p.S842F | Missense Mutation (SNP) | VAF 123/340 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.452); catalogued as rs374027043; called by muse, mutect2, varscan2
- NPBWR2 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 266/735 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs757392628; called by muse, mutect2, varscan2
- NXPE4 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 81/288 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV64944418; called by muse, mutect2, varscan2
- NYAP2 | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 97/327 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs1258832971, COSV56005333; called by muse, mutect2, varscan2
- ODF2L | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54013925; called by muse, mutect2
- OLFM2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 126/254 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as rs1006248870; called by muse, mutect2, varscan2
- OR10Z1 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 55/394 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100779083; called by muse, mutect2, varscan2
- OR11L1 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 286/447 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV63314989; called by muse, mutect2, varscan2
- OR1N2 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 145/313 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319418425, COSV65460863; called by muse, mutect2, varscan2
- OR4C46 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 86/243 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs751837741; called by muse, mutect2, varscan2
- OR51T1 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 76/259 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as rs373780146; called by muse, mutect2, varscan2
- OR52E2 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58611731; called by muse, mutect2
- OR6C75 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 66/260 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as COSV100595478; called by muse, mutect2, varscan2
- OR8D2 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 86/234 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs781713212, COSV62489282; called by muse, mutect2, varscan2
- PAK5 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 149/390 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.227); catalogued as COSV100781839; called by muse, mutect2, varscan2
- PASD1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 158/456 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as COSV64854218, COSV64854680; called by muse, mutect2, varscan2
- PCDHGA6 | c.2314C>T p.Q772* | Nonsense Mutation (SNP) | VAF 60/208 reads (29%) | catalogued as rs761002002, COSV99539344; called by muse, mutect2, varscan2
- PCED1B | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 86/386 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs768597323, COSV71395107; called by muse, mutect2, varscan2
- PCLO | c.14728G>A p.E4910K | Missense Mutation (SNP) | VAF 296/484 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs751146334, COSV61629563; called by muse, mutect2, varscan2
- PENK | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 168/427 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs759815705, COSV59240234; called by muse, mutect2, varscan2
- PHLPP1 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 85/126 reads (67%) | SIFT deleterious, low confidence (0.02); catalogued as rs1231742335; called by muse, mutect2, varscan2
- PLCB2 | c.1481G>A p.G494D | Missense Mutation (SNP) | VAF 122/338 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1466739438; called by muse, mutect2, varscan2
- PLCH2 | c.2515G>A p.D839N | Missense Mutation (SNP) | VAF 108/482 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774739158; called by muse, mutect2, varscan2
- POLR2G | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57135164; called by muse, mutect2, varscan2
- POLRMT | c.3061C>T p.P1021S | Missense Mutation (SNP) | VAF 59/274 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs753927804, COSV52116830; called by muse, mutect2
- POTEE | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 108/418 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as rs370006093; called by muse, mutect2, varscan2
- POTEG | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 57/496 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); catalogued as rs1209834857; called by muse, mutect2, varscan2
- PRKRA | c.935G>A p.R312K | Missense Mutation (SNP) | VAF 236/476 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100359640; called by muse, mutect2
- PRR30 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 84/322 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); catalogued as rs957112679; called by muse, mutect2, varscan2
- PRR5L | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 88/286 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as rs866924836, COSV61123354; called by muse, mutect2
- PSG4 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 73/381 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.2); catalogued as rs1310243477, COSV54937305; called by muse, mutect2, varscan2
- PTK2B | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 116/399 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.157); catalogued as COSV57756401; called by muse, mutect2
- RBMX | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 166/540 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV57811852; called by muse, mutect2, varscan2
- ROBO1 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 106/188 reads (56%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV71974762; called by muse, mutect2, varscan2
- ROR2 | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 242/501 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs1366867361; called by muse, mutect2, varscan2
- ROS1 | c.5057G>A p.R1686K | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.174); catalogued as COSV100876137; called by muse, mutect2, varscan2
- RP1L1 | c.4972C>T p.P1658S | Missense Mutation (SNP) | VAF 202/564 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV66751898; called by muse, mutect2, varscan2
- RTL1 | c.3389C>T p.S1130L | Missense Mutation (SNP) | VAF 205/378 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1369855247, COSV66016375; called by muse, mutect2, varscan2
- RYR2 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 86/573 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV100771587; called by muse, mutect2, varscan2
- SACS | c.12493C>T p.H4165Y | Missense Mutation (SNP) | VAF 133/363 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as COSV66545744; called by muse, mutect2, varscan2
- SCN5A | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 110/212 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs1404917416, COSV100349231; called by muse, mutect2, varscan2
- SEMA3E | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 73/423 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.045); catalogued as COSV100318920; called by muse, mutect2, varscan2
- SHANK1 | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 105/474 reads (22%) | catalogued as rs753079097; called by muse, mutect2, varscan2
- SHISA6 | c.1162C>G p.R388G (on ENST00000409168 / NM_001173461.1; = p.R439G on NM_207386.4) | Missense Mutation (SNP) | VAF 93/450 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs556936959, COSV101305744; called by muse, mutect2, varscan2
- SHISA6 | c.1388C>T p.T463M (on ENST00000409168 / NM_001173461.1; = p.T514M on NM_207386.4) | Missense Mutation (SNP) | VAF 216/436 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as rs549533522, COSV69388410; called by muse, mutect2, varscan2
- SHISA9 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 90/363 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.702); catalogued as rs900500761, COSV69644591; called by muse, mutect2, varscan2
- SHROOM2 | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 121/337 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.55); catalogued as rs1471661833; called by muse, mutect2, varscan2
- SIGLEC12 | c.1361C>T p.S454F (on ENST00000291707 / NM_053003.4; = p.S336F on NM_033329.2) | Missense Mutation (SNP) | VAF 149/322 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs267605619, COSV52460508, COSV52463954; called by muse, mutect2, varscan2
- SLC10A2 | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 105/269 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs758275143; called by muse, mutect2, varscan2
- SLC16A14 | c.1505G>A p.R502K | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99725505; called by muse, mutect2, varscan2
- SLC16A14 | c.271G>C p.G91R | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV54617699; called by muse, mutect2, varscan2
- SLC5A8 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 94/206 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV73310331, COSV73310495; called by muse, mutect2, varscan2
- SLIT2 | c.2977G>A p.E993K | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.21); catalogued as COSV56600156; called by muse, mutect2, varscan2
- SOHLH2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 118/282 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV65901841; called by muse, mutect2, varscan2
- SPDYE4 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs958666208, COSV60905291; called by muse, mutect2, varscan2
- SSUH2 | c.381G>A p.W127* | Nonsense Mutation (SNP) | VAF 99/392 reads (25%) | catalogued as rs977417101; called by muse, mutect2, varscan2
- STAT4 | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV61827835, COSV61828418; called by muse, mutect2, varscan2
- STOX1 | c.2774G>A p.G925E | Missense Mutation (SNP) | VAF 143/202 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as rs1344105162; called by muse, mutect2, varscan2
- SVEP1 | c.9586G>A p.D3196N | Missense Mutation (SNP) | VAF 94/416 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.323); catalogued as rs267602083, COSV52843809; called by muse, mutect2
- SVIL | c.3413G>A p.G1138E (on ENST00000355867 / NM_021738.3; = p.G712E on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/215 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100880813; called by muse, mutect2, varscan2
- SVIL | c.3412G>A p.G1138R (on ENST00000355867 / NM_021738.3; = p.G712R on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 131/211 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781045248; called by muse, mutect2, varscan2
- SYNGR1 | c.16T>C p.Y6H | Missense Mutation (SNP) | VAF 95/255 reads (37%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1298211239; called by muse, mutect2, varscan2
- TAFA2 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1485194609, COSV69178650; called by muse, mutect2, varscan2
- TAS2R60 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 331/507 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767812355, COSV60330541; called by muse, mutect2, varscan2
- TCHHL1 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 57/473 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV64286196; called by muse, mutect2, varscan2
- TDRD1 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 80/129 reads (62%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV52593947; called by muse, mutect2, varscan2
- TENM1 | c.4208C>T p.P1403L | Missense Mutation (SNP) | VAF 146/360 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1447366465; called by muse, mutect2, varscan2
- TIPIN | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 157/434 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs756403375; called by muse, mutect2, varscan2
- TLL1 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV50261937; called by mutect2, varscan2
- TLR7 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 178/495 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.347); catalogued as rs1218801965, COSV66124434; called by muse, mutect2, varscan2
- TLR9 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 86/384 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1421960438; called by muse, mutect2, varscan2
- TMEM245 | c.929G>A p.R310K | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs778877244; called by muse, mutect2, varscan2
- TNC | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 94/426 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs773953939, COSV60783280; called by muse, mutect2, varscan2
- TNS1 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 107/348 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.114); catalogued as rs1559229378; called by muse, mutect2, varscan2
- TP63 | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 118/212 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.835); catalogued as rs749906547, COSV53214167; called by muse, mutect2, varscan2
- TRANK1 | c.4165G>A p.E1389K | Missense Mutation (SNP) | VAF 138/316 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs369260304; called by muse, mutect2, varscan2
- TRIM10 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 593/1198 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs367573300; called by muse, mutect2, varscan2
- TRMT6 | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 160/469 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV52542755; called by muse, mutect2, varscan2
- TSHB | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.761); catalogued as rs778884161; called by muse, mutect2, varscan2
- TTN | c.68658G>T p.K22886N (on ENST00000591111; = p.K15462N on NM_003319.4) | Missense Mutation (SNP) | VAF 74/225 reads (33%) | PolyPhen possibly damaging (0.472); catalogued as rs763480481; called by muse, mutect2, varscan2
- TTN | c.33472G>A p.E11158K (on ENST00000591111; = p.E10231K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | PolyPhen benign (0.418); catalogued as COSV59960368; called by muse, mutect2, varscan2
- TTN | c.30604C>T p.H10202Y (on ENST00000591111; = p.H9275Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/165 reads (22%) | PolyPhen benign (0.094); catalogued as COSV100595782; called by muse, mutect2
- TUBD1 | c.286C>G p.Q96E | Missense Mutation (SNP) | VAF 68/308 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as COSV57872885; called by muse, mutect2, varscan2
- TYW1B | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 66/531 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59270216; called by muse, mutect2, varscan2
- UCKL1 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 138/412 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV100700525; called by muse, mutect2
- USP25 | c.1774C>T p.R592* | Nonsense Mutation (SNP) | VAF 83/240 reads (35%) | catalogued as rs201924129, COSV53484056; called by muse, mutect2, varscan2
- VSTM2A | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 66/395 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); catalogued as COSV68289335; called by muse, mutect2, varscan2
- XKRX | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 170/459 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100139715; called by muse, mutect2, varscan2
- ZAN | c.2962G>A p.E988K | Missense Mutation (SNP) | VAF 506/839 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV61808512; called by muse, mutect2, varscan2
- ZC3HC1 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 53/359 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV61298056; called by muse, mutect2, varscan2
- ZEB1 | c.2594G>A p.G865E | Missense Mutation (SNP) | VAF 87/138 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58042383; called by muse, mutect2, varscan2
- ZNF334 | c.1996C>T p.R666C | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs763384880, COSV61617978; called by muse, mutect2, varscan2
- ZNF493 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV62749807; called by muse, mutect2, varscan2
- ZNF630 | c.1615G>A p.G539R | Missense Mutation (SNP) | VAF 234/587 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as rs1458458363; called by muse, mutect2, varscan2
- ZNF679 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 71/527 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.155); catalogued as rs745552363, COSV55376356; called by muse, mutect2, varscan2
- ZNF865 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 129/536 reads (24%) | SIFT deleterious, low confidence (0.04); catalogued as rs1340225497; called by muse, mutect2, varscan2
- ZNF91 | c.3466C>T p.H1156Y | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as rs868387314; called by muse, mutect2, varscan2
- ZSCAN31 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 81/631 reads (13%) | catalogued as rs1426415828; called by muse, mutect2, varscan2
- ZSWIM8 | c.4936C>T p.P1646S (on ENST00000605216 / NM_001242487.2; = p.P1651S on NM_015037.3) | Missense Mutation (SNP) | VAF 226/362 reads (62%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.943); catalogued as rs1478712089; called by muse, mutect2, varscan2
- ADAMTS20 | c.1870G>A p.D624N | Missense Mutation (SNP) | VAF 75/296 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ADCY7 | c.3037G>A p.G1013R | Missense Mutation (SNP) | VAF 111/240 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.10036G>A p.G3346R | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ADH1B | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- AIMP1 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 88/322 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- AKAP11 | c.4861C>T p.P1621S | Missense Mutation (SNP) | VAF 179/405 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP6 | c.3598A>T p.N1200Y | Missense Mutation (SNP) | VAF 96/185 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ALOX15 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 106/244 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- AMHR2 | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 175/424 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMPD1 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 77/382 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ANKRD30B | c.1318C>T p.L440F | Missense Mutation (SNP) | VAF 96/157 reads (61%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD31 | c.1472A>T p.N491I | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANKS1B | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ANTXR1 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- ARHGAP6 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 260/662 reads (39%) | called by muse, mutect2, varscan2
- ARHGEF16 | c.1891C>T p.L631= | Splice Region (SNP) | VAF 104/230 reads (45%) | called by muse, varscan2
- ASAH2 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 82/157 reads (52%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- BARX2 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BEND3 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 118/315 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BMP15 | c.1131G>T p.L377F | Missense Mutation (SNP) | VAF 122/315 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRDT | c.2389G>A p.D797N | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- C12orf43 | c.773del p.A258Vfs*53 | Frame Shift Del (DEL) | VAF 58/291 reads (20%) | called by mutect2, pindel, varscan2
- C17orf113 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- C19orf57 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 228/473 reads (48%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- C3 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 70/276 reads (25%) | called by muse, mutect2, varscan2
- C8orf33 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 118/316 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CACNG8 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 118/308 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CAMK2B | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 375/613 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC141 | c.4006C>T p.P1336S | Missense Mutation (SNP) | VAF 61/218 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCDC150 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC9 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 218/432 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCNQ | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 111/296 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDKN2A | c.200dup p.A68Rfs*52 | Frame Shift Ins (INS) | VAF 232/452 reads (51%) | called by mutect2, pindel, varscan2
- CDR1 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 204/554 reads (37%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- CEACAM16 | c.413A>G p.N138S | Missense Mutation (SNP) | VAF 94/208 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- CHPT1 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CHRNA6 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 182/487 reads (37%) | called by muse, mutect2, varscan2
- CMTR2 | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COL11A2 | c.3121C>T p.P1041S (on ENST00000341947 / NM_080680.3; = p.P934S on NM_080679.2) | Missense Mutation (SNP) | VAF 82/828 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- COL18A1 | c.2854C>T p.P952S (on ENST00000359759 / NM_130444.3; = p.P717S on NM_030582.4) | Missense Mutation (SNP) | VAF 118/311 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- COL5A3 | c.3899C>T p.S1300F | Missense Mutation (SNP) | VAF 79/395 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- COL9A1 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- COL9A2 | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 141/305 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- CPSF3 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRISP2 | c.646T>G p.S216A | Missense Mutation (SNP) | VAF 67/219 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CRYBA2 | c.233G>A p.W78* | Nonsense Mutation (SNP) | VAF 83/292 reads (28%) | called by muse, mutect2, varscan2
- CYP46A1 | c.1160G>A p.G387D | Missense Mutation (SNP) | VAF 113/226 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- DAPK2 | c.1026G>C p.E342D | Missense Mutation (SNP) | VAF 142/374 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIP2A | c.3350C>T p.A1117V | Missense Mutation (SNP) | VAF 127/372 reads (34%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- DIS3L2 | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 116/399 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAH1 | c.9943C>T p.P3315S | Missense Mutation (SNP) | VAF 110/471 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- DNAH6 | c.4975T>A p.L1659I | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAH6 | c.7882G>A p.E2628K | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- DNAH6 | c.10416G>A p.M3472I | Missense Mutation (SNP) | VAF 78/257 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJA3 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 67/283 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJC6 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 104/228 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DOCK3 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 77/302 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- DST | c.20546T>A p.L6849H (on ENST00000361203 / NM_001374722.1; = p.L4546H on NM_015548.5) | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ECSIT | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 83/353 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ENPP3 | c.1164T>A p.D388E | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FAM155B | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 271/713 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- FAM228A | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FAM47A | c.2079G>A p.M693I | Missense Mutation (SNP) | VAF 166/503 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FAM90A26 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 134/167 reads (80%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FANCD2 | c.3269C>T p.A1090V | Missense Mutation (SNP) | VAF 109/227 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FBXO28 | c.1098T>G p.N366K | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FLNB | c.5872C>T p.P1958S | Missense Mutation (SNP) | VAF 128/270 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- FNDC1 | c.4018G>A p.G1340R | Missense Mutation (SNP) | VAF 103/244 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FOLH1 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- G6PC2 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 112/372 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- GAGE2A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 154/2807 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2
- GC | c.21+1G>A p.X7_splice | Splice Site (SNP) | VAF 71/332 reads (21%) | called by muse, mutect2, varscan2
- GGT2 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GLB1 | c.1974A>C p.E658D | Missense Mutation (SNP) | VAF 17/322 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.023); called by muse, mutect2
- GM2A | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 75/278 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- GPC5 | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 100/272 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GRIPAP1 | c.2353G>A p.D785N | Missense Mutation (SNP) | VAF 191/482 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- H4C7 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 139/494 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- HEPHL1 | c.3332G>A p.G1111E | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HYDIN | c.7591G>A p.A2531T | Missense Mutation (SNP) | VAF 92/475 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.797); called by muse, varscan2
- IGFN1 | c.2128G>A p.E710K (on ENST00000295591 / NM_001367841.1; = p.E3167K on NM_001164586.2) | Missense Mutation (SNP) | VAF 135/741 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- IGHM | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 76/382 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- IL7R | c.274T>A p.Y92N | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- INSC | c.1386G>T p.Q462H | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- KANK4 | c.2815C>T p.H939Y | Missense Mutation (SNP) | VAF 116/473 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.057); called by muse, mutect2
- KCNA5 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 230/480 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- KCNH4 | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 110/412 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KCNH5 | c.2381G>A p.C794Y | Missense Mutation (SNP) | VAF 68/280 reads (24%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KDR | c.532T>A p.S178T | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1549L | c.781C>T p.P261S (on ENST00000321505; = p.P558S on NM_012194.3) | Missense Mutation (SNP) | VAF 97/228 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIF6 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 323/470 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- KMT2D | c.16061C>T p.T5354I | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRBA2 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT13 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- KRT9 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 63/329 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- LAMC3 | c.2555G>A p.G852E | Missense Mutation (SNP) | VAF 132/295 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LDB2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 154/323 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LDHC | c.602G>A p.W201* | Nonsense Mutation (SNP) | VAF 44/137 reads (32%) | called by muse, mutect2, varscan2
- LPCAT3 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRP1 | c.8185C>T p.H2729Y | Missense Mutation (SNP) | VAF 105/261 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAP1B | c.2255C>T p.P752L | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MAPKAPK2 | c.745C>A p.L249M | Missense Mutation (SNP) | VAF 205/334 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MAPT | c.1864C>T p.R622C (on ENST00000262410 / NM_001377265.1; = p.R230C on NM_005910.5) | Missense Mutation (SNP) | VAF 225/498 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MBTPS2 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 145/415 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MEGF6 | c.4562C>T p.S1521L | Missense Mutation (SNP) | VAF 70/328 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MERTK | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MET | c.3027A>C p.E1009D | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MEX3D | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 146/632 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MFSD8 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM2 | c.2523G>A p.M841I | Missense Mutation (SNP) | VAF 54/353 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- NEK10 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 146/303 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- NETO2 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NHS | c.2734C>T p.P912S | Missense Mutation (SNP) | VAF 196/571 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NLGN1 | c.2111G>A p.R704K | Missense Mutation (SNP) | VAF 163/244 reads (67%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- NOTCH3 | c.4459G>A p.G1487S | Missense Mutation (SNP) | VAF 206/456 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- NPAP1 | c.1664C>T p.S555F | Missense Mutation (SNP) | VAF 142/407 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, varscan2
- NR2E1 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 90/422 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NTN1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 195/406 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- OR11H7 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 90/207 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- OR13C4 | c.575T>G p.I192R | Missense Mutation (SNP) | VAF 91/204 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR2M7 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 257/419 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OR4D5 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 75/264 reads (28%) | called by muse, mutect2, varscan2
- OR51I2 | c.711_712insTT p.L238Ffs*19 | Frame Shift Ins (INS) | VAF 32/133 reads (24%) | called by mutect2, varscan2
- OR56A1 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 104/338 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- PALD1 | c.1078A>T p.S360C | Missense Mutation (SNP) | VAF 204/286 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- PCDHGA5 | c.1740_1741insAT p.S581Ifs*9 | Frame Shift Ins (INS) | VAF 102/375 reads (27%) | called by muse*, mutect2, varscan2*
- PCDHGA5 | c.1742_1743del p.S581Cfs*29 | Frame Shift Del (DEL) | VAF 104/388 reads (27%) | called by muse*, mutect2, varscan2*
- PEAK3 | c.42C>A p.D14E | Missense Mutation (SNP) | VAF 169/397 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- PHLPP1 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 85/132 reads (64%) | SIFT tolerated, low confidence (0.23); called by muse, mutect2, varscan2
- PHRF1 | c.3266C>G p.S1089C (on ENST00000264555 / NM_001286581.2; = p.S1088C on NM_020901.4) | Missense Mutation (SNP) | VAF 107/360 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- PLXDC1 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 81/360 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- PLXNA3 | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 232/650 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- PP2D1 | c.284G>A p.W95* | Nonsense Mutation (SNP) | VAF 157/332 reads (47%) | called by muse, mutect2, varscan2
- PPP1R13L | c.2296C>T p.L766F | Missense Mutation (SNP) | VAF 219/481 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRAMEF4 | c.570G>T p.L190F | Missense Mutation (SNP) | VAF 115/357 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- PTGFR | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 98/312 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAI1 | c.3959C>T p.P1320L | Missense Mutation (SNP) | VAF 98/477 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RANBP2 | c.9507T>A p.N3169K | Missense Mutation (SNP) | VAF 82/262 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- RELN | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 172/270 reads (64%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RGPD3 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RGS9 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 273/550 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- RHBDD1 | c.853C>G p.R285G | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RORB | c.196G>A p.D66N (on ENST00000396204 / NM_001365023.1; = p.D55N on NM_006914.4) | Missense Mutation (SNP) | VAF 78/353 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RP1 | c.1735T>C p.Y579H | Missense Mutation (SNP) | VAF 131/317 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPGRIP1L | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 68/306 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- RSPH9 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 244/687 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- RXRB | c.781C>G p.R261G | Missense Mutation (SNP) | VAF 100/927 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RYR2 | c.11669G>A p.W3890* | Nonsense Mutation (SNP) | VAF 40/238 reads (17%) | called by muse, mutect2, varscan2
- S1PR5 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 207/445 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- SEC16B | c.2819C>T p.S940F | Missense Mutation (SNP) | VAF 51/376 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- SEC63 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SELE | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 302/506 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA4B | c.2145G>A p.W715* | Nonsense Mutation (SNP) | VAF 202/550 reads (37%) | called by muse, mutect2, varscan2
- SH3BGRL | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 149/406 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SHC4 | c.1220A>T p.Q407L | Missense Mutation (SNP) | VAF 62/321 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC22A11 | c.943-1G>A p.X315_splice | Splice Site (SNP) | VAF 59/179 reads (33%) | called by muse, mutect2, varscan2
- SLC22A6 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 83/278 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SLC38A9 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SLC5A7 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMARCA4 | c.2737C>T p.P913S | Missense Mutation (SNP) | VAF 163/373 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SMPX | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 74/241 reads (31%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNAP91 | c.251A>T p.H84L | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPAG11B | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 100/644 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- SSR4 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 160/443 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- STARD13 | c.733C>T p.H245Y (on ENST00000336934 / NM_001243476.3; = p.H127Y on NM_052851.3) | Missense Mutation (SNP) | VAF 180/485 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- STBD1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 92/469 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SULT4A1 | c.746G>A p.R249K | Missense Mutation (SNP) | VAF 105/294 reads (36%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- SV2A | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, varscan2
- SVOP | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 131/304 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- TBCEL | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 60/160 reads (38%) | called by muse, mutect2, varscan2
- TCTN3 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 110/176 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- TESMIN | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 74/274 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TIGD7 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 108/269 reads (40%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM40 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 178/376 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- TMPRSS9 | c.736G>A p.G246R (on ENST00000648592; = p.G212R on NM_182973.2) | Missense Mutation (SNP) | VAF 171/356 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMPRSS9 | c.737G>A p.G246E (on ENST00000648592; = p.G212E on NM_182973.2) | Missense Mutation (SNP) | VAF 172/357 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNFRSF8 | c.677-1G>A p.X226_splice | Splice Site (SNP) | VAF 60/245 reads (24%) | called by muse, mutect2, varscan2
- TNFSF15 | c.283C>G p.P95A | Missense Mutation (SNP) | VAF 88/424 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- TNR | c.2795G>A p.S932N | Missense Mutation (SNP) | VAF 360/539 reads (67%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- TNXB | c.7187C>T p.T2396I (on ENST00000647633; = p.T2149I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 630/907 reads (69%) | SIFT tolerated (0.12); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- TP73 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 121/250 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- TPTE | c.1574G>A p.R525K (on ENST00000618007 / NM_199261.4; = p.R507K on NM_199259.4) | Missense Mutation (SNP) | VAF 113/688 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TRIM29 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 111/317 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM43B | c.445A>T p.K149* | Nonsense Mutation (SNP) | VAF 41/182 reads (23%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.1909G>A p.D637N | Missense Mutation (SNP) | VAF 91/363 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- TTLL9 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 85/243 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TTN | c.43936G>A p.E14646K (on ENST00000591111; = p.E7222K on NM_003319.4) | Missense Mutation (SNP) | VAF 74/247 reads (30%) | PolyPhen benign (0.169); called by muse, mutect2, varscan2
- TTN | c.26189C>T p.P8730L (on ENST00000591111; = p.P7803L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/296 reads (27%) | PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- UBE2QL1 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- UCN | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 119/384 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- UNC13C | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 171/451 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UROC1 | c.813G>A p.E271= | Splice Region (SNP) | VAF 124/205 reads (60%) | called by muse, mutect2, varscan2
- VCX | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 184/756 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- WDR87 | c.4456G>A p.E1486K | Missense Mutation (SNP) | VAF 70/326 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- ZC3H11B | c.2337G>A p.W779* | Nonsense Mutation (SNP) | VAF 33/384 reads (9%) | called by muse, mutect2
- ZCCHC10 | c.202C>T p.P68S (on ENST00000509437 / NM_001300818.3; = p.P46S on NM_017665.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ZFHX4 | c.10640C>T p.S3547F | Missense Mutation (SNP) | VAF 118/354 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- ZNF469 | c.2414C>T p.A805V | Missense Mutation (SNP) | VAF 106/490 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF804A | c.2170T>G p.C724G | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN4 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 69/311 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- ABCC10 | c.3054C>T p.A1018= (on ENST00000372530 / NM_001198934.2; = p.A990= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/398 reads (14%) | called by muse, mutect2, varscan2
- ACTL6B | c.903C>T p.I301= | Silent (SNP) | VAF 45/383 reads (12%) | catalogued as COSV99355516; called by muse, mutect2, varscan2
- ADGRD1 | c.1590G>A p.T530= | Silent (SNP) | VAF 81/347 reads (23%) | catalogued as rs1438137558, COSV55445237; called by muse, mutect2, varscan2
- AGL | c.2304C>T p.I768= | Silent (SNP) | VAF 41/165 reads (25%) | called by muse, mutect2, varscan2
- AL451106.1 | c.40C>T p.L14= | Silent (SNP) | VAF 132/389 reads (34%) | called by muse, mutect2, varscan2
- ALG8 | c.120C>T p.H40= | Silent (SNP) | VAF 68/211 reads (32%) | called by muse, mutect2, varscan2
- ANKRD30A | c.2859A>G p.G953= (on ENST00000611781; = p.G897= on NM_052997.2) | Silent (SNP) | VAF 51/64 reads (80%) | called by muse, mutect2, varscan2
- ANKRD31 | c.1473C>T p.N491= | Silent (SNP) | VAF 69/242 reads (29%) | catalogued as COSV99166273; called by muse, mutect2, varscan2
- ANXA7 | c.789C>T p.A263= (on ENST00000372919 / NM_001320880.2; = p.A241= on NM_001156.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 139/215 reads (65%) | called by muse, mutect2, varscan2
- ARGLU1 | c.330C>T p.F110= | Silent (SNP) | VAF 99/273 reads (36%) | catalogued as rs557130358; called by muse, mutect2, varscan2
- ASCC2 | c.717C>T p.L239= | Silent (SNP) | VAF 101/293 reads (34%) | catalogued as COSV57072429; called by muse, mutect2, varscan2
- ASTE1 | c.357C>T p.I119= | Silent (SNP) | VAF 125/201 reads (62%) | called by muse, mutect2, varscan2
- ATF2 | c.1380C>T p.S460= | Silent (SNP) | VAF 78/261 reads (30%) | called by muse, mutect2, varscan2
- ATG4B | c.1170C>T p.I390= | Silent (SNP) | VAF 78/231 reads (34%) | called by muse, mutect2, varscan2
- ATP1A3 | c.2520G>A p.R840= (on ENST00000545399 / NM_001256214.2; = p.R827= on NM_152296.5) | Silent (SNP) | VAF 142/332 reads (43%) | catalogued as rs1555859513, COSV57489402; called by muse, mutect2, varscan2
- B3GAT1 | c.189C>T p.I63= | Silent (SNP) | VAF 124/448 reads (28%) | catalogued as rs201436728; called by muse, mutect2, varscan2
- BLM | c.2187C>T p.S729= | Silent (SNP) | VAF 81/194 reads (42%) | called by muse, mutect2, varscan2
- BPGM | c.342C>T p.L114= | Silent (SNP) | VAF 42/317 reads (13%) | called by muse, mutect2, varscan2
- C1QB | c.414C>T p.I138= | Silent (SNP) | VAF 74/354 reads (21%) | called by muse, mutect2, varscan2
- C2orf16 | c.4530C>T p.S1510= | Silent (SNP) | VAF 66/205 reads (32%) | called by muse, mutect2, varscan2
- C6 | c.1599C>T p.T533= | Silent (SNP) | VAF 62/230 reads (27%) | called by muse, mutect2, varscan2
- C8B | c.1260G>A p.V420= | Silent (SNP) | VAF 119/259 reads (46%) | catalogued as rs1045562025, COSV100980722; called by muse, mutect2, varscan2
- CACNA1B | c.2685G>A p.E895= | Silent (SNP) | VAF 105/264 reads (40%) | called by muse, mutect2, varscan2
- CACNA1E | c.6453C>T p.T2151= (on ENST00000367573 / NM_001205293.3; = p.T2108= on NM_000721.4) | Silent (SNP) | VAF 81/511 reads (16%) | catalogued as rs1372670914, COSV62401435; called by muse, mutect2, varscan2
- CACNA2D3 | c.1863C>T p.S621= | Silent (SNP) | VAF 63/292 reads (22%) | catalogued as COSV55528744; called by muse, mutect2, varscan2
- CBX8 | c.312C>T p.I104= | Silent (SNP) | VAF 247/542 reads (46%) | called by muse, mutect2, varscan2
- CCDC168 | c.17694G>A p.G5898= | Silent (SNP) | VAF 162/477 reads (34%) | catalogued as COSV100487659; called by muse, mutect2, varscan2
- CCER1 | c.492G>A p.A164= | Silent (SNP) | VAF 240/523 reads (46%) | catalogued as COSV100727128; called by muse, mutect2, varscan2
- CCSER1 | c.1782C>T p.I594= | Silent (SNP) | VAF 139/300 reads (46%) | called by muse, varscan2
- CD300LF | c.702G>A p.V234= | Silent (SNP) | VAF 73/271 reads (27%) | catalogued as rs1378511765; called by muse, mutect2, varscan2
- CD300LG | c.906C>T p.A302= | Silent (SNP) | VAF 90/206 reads (44%) | called by muse, varscan2
- CEACAM7 | c.603C>T p.L201= | Silent (SNP) | VAF 63/339 reads (19%) | catalogued as rs199809426, COSV50072688; called by muse, mutect2, varscan2
- CHD5 | c.1257C>T p.C419= | Silent (SNP) | VAF 87/452 reads (19%) | called by muse, mutect2, varscan2
- CHID1 | c.558C>T p.F186= | Silent (SNP) | VAF 65/198 reads (33%) | catalogued as rs535895676, COSV60258265; called by muse, mutect2, varscan2
- CLEC4G | c.720G>A p.V240= | Silent (SNP) | VAF 71/291 reads (24%) | called by muse, mutect2, varscan2
- CLVS1 | c.249G>A p.R83= | Silent (SNP) | VAF 141/416 reads (34%) | catalogued as rs866957503, COSV57983278; called by muse, mutect2, varscan2
- COL11A1 | c.1272G>A p.E424= | Silent (SNP) | VAF 66/312 reads (21%) | catalogued as rs1457152357; called by muse, mutect2, varscan2
- COL11A2 | c.3120C>T p.P1040= (on ENST00000341947 / NM_080680.3; = p.P933= on NM_080679.2) | Silent (SNP) | VAF 84/837 reads (10%) | catalogued as COSV100554671; called by muse, mutect2, varscan2
- COL4A3 | c.3054G>A p.G1018= | Silent (SNP) | VAF 91/225 reads (40%) | called by muse, mutect2, varscan2
- COL4A4 | c.2739C>T p.F913= | Silent (SNP) | VAF 69/244 reads (28%) | catalogued as COSV61631451; called by muse, mutect2, varscan2
- COL5A1 | c.3171T>C p.G1057= | Silent (SNP) | VAF 109/421 reads (26%) | catalogued as rs943030077, COSV65671486; ClinVar: likely benign; called by muse, mutect2, varscan2
- CPNE3 | c.1047T>C p.A349= | Silent (SNP) | VAF 31/317 reads (10%) | catalogued as rs748831746; called by muse, mutect2
- CR1L | c.579G>A p.G193= | Silent (SNP) | VAF 309/498 reads (62%) | catalogued as COSV54323071; called by muse, mutect2, varscan2
- CRAMP1 | c.1482C>T p.A494= | Silent (SNP) | VAF 225/480 reads (47%) | called by muse, mutect2, varscan2
- CSGALNACT1 | c.444C>T p.F148= | Silent (SNP) | VAF 207/460 reads (45%) | catalogued as rs537689859; called by muse, mutect2, varscan2
- DDX23 | c.195C>T p.S65= | Silent (SNP) | VAF 82/284 reads (29%) | catalogued as COSV100339690; called by muse, mutect2, varscan2
- DDX4 | c.369G>A p.R123= | Silent (SNP) | VAF 45/181 reads (25%) | called by muse, mutect2, varscan2
- DDX49 | c.942C>T p.I314= | Silent (SNP) | VAF 70/341 reads (21%) | called by muse, mutect2, varscan2
- DGKB | c.2106G>A p.E702= | Silent (SNP) | VAF 176/275 reads (64%) | catalogued as COSV51761907; called by muse, mutect2, varscan2
- DMD | c.4734G>A p.K1578= | Silent (SNP) | VAF 128/356 reads (36%) | called by muse, mutect2, varscan2
- DNAH6 | c.3654G>A p.R1218= | Silent (SNP) | VAF 64/271 reads (24%) | catalogued as COSV52856187; called by muse, mutect2, varscan2
- DOCK3 | c.1299C>T p.F433= | Silent (SNP) | VAF 82/228 reads (36%) | catalogued as rs139890793; called by muse, mutect2, varscan2
- EHD2 | c.1539C>T p.I513= | Silent (SNP) | VAF 170/356 reads (48%) | catalogued as rs752410169, COSV54407112; called by muse, mutect2, varscan2
- ELP1 | c.2391C>T p.Y797= | Silent (SNP) | VAF 51/262 reads (19%) | called by muse, mutect2, varscan2
- EPHB2 | c.684C>T p.A228= | Silent (SNP) | VAF 95/393 reads (24%) | called by muse, mutect2, varscan2
- EPHB2 | c.1881C>T p.I627= (on ENST00000400191 / NM_001309193.2; = p.I628= on NM_004442.7) | Silent (SNP) | VAF 112/264 reads (42%) | catalogued as rs371734479; called by mutect2, varscan2
- ERCC6 | c.417C>T p.D139= | Silent (SNP) | VAF 95/175 reads (54%) | called by muse, mutect2, varscan2
- ESPN | c.381C>T p.G127= | Silent (SNP) | VAF 110/398 reads (28%) | catalogued as rs552379031, COSV64704957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXL18 | c.645C>T p.G215= | Silent (SNP) | VAF 119/728 reads (16%) | called by muse, mutect2, varscan2
- FBXO7 | c.1290C>T p.H430= | Silent (SNP) | VAF 191/535 reads (36%) | catalogued as rs765859072; called by muse, mutect2, varscan2
- FKRP | c.207C>T p.S69= | Silent (SNP) | VAF 109/508 reads (21%) | called by muse, mutect2, varscan2
- FNDC7 | c.492C>T p.S164= | Silent (SNP) | VAF 80/363 reads (22%) | called by muse, mutect2, varscan2
- GABRA3 | c.45G>A p.G15= | Silent (SNP) | VAF 92/256 reads (36%) | catalogued as COSV64800102; called by muse, mutect2, varscan2
- GABRA6 | c.1173C>T p.L391= | Silent (SNP) | VAF 88/323 reads (27%) | called by muse, mutect2, varscan2
- GABRB3 | c.306C>T p.I102= | Silent (SNP) | VAF 180/473 reads (38%) | called by muse, mutect2, varscan2
- GABRR3 | c.414G>A p.K138= | Silent (SNP) | VAF 140/207 reads (68%) | catalogued as COSV72084177; called by muse, mutect2, varscan2
- GPR137B | c.486C>T p.S162= | Silent (SNP) | VAF 219/366 reads (60%) | called by muse, mutect2, varscan2
- H1-6 | c.177A>G p.V59= | Silent (SNP) | VAF 67/589 reads (11%) | called by muse, mutect2, varscan2
- HAAO | c.736C>T p.L246= | Silent (SNP) | VAF 102/369 reads (28%) | called by muse, mutect2, varscan2
- HGFAC | c.1302G>A p.G434= | Silent (SNP) | VAF 235/476 reads (49%) | catalogued as rs1429259037; called by muse, mutect2, varscan2
- IFFO2 | c.6G>C p.V2= | Silent (SNP) | VAF 32/157 reads (20%) | called by muse, mutect2, varscan2
- IGKV2-24 | c.9C>T p.L3= | Silent (SNP) | VAF 35/196 reads (18%) | called by muse, mutect2, varscan2
- IGKV2D-24 | c.90C>T p.S30= | Silent (SNP) | VAF 51/182 reads (28%) | catalogued as rs1288886850; called by muse, mutect2, varscan2
- IL13RA2 | c.750T>C p.S250= | Silent (SNP) | VAF 126/345 reads (37%) | called by muse, mutect2, varscan2
- IL20RA | c.535C>T p.L179= | Silent (SNP) | VAF 137/330 reads (42%) | called by muse, mutect2, varscan2
- IMPG1 | c.72C>T p.I24= | Silent (SNP) | VAF 36/100 reads (36%) | called by muse, mutect2, varscan2
- IRF2BPL | c.903T>C p.G301= | Silent (SNP) | VAF 172/374 reads (46%) | called by muse, varscan2
- ITGAX | c.3135C>T p.F1045= | Silent (SNP) | VAF 70/314 reads (22%) | catalogued as COSV51645524; called by muse, mutect2, varscan2
- KAT2B | c.1611C>T p.L537= | Silent (SNP) | VAF 46/235 reads (20%) | catalogued as rs1198200315, COSV55429112; called by muse, mutect2, varscan2
- KCNH5 | c.855G>A p.R285= | Silent (SNP) | VAF 62/309 reads (20%) | catalogued as COSV100526591, COSV59777439; called by muse, mutect2, varscan2
- KIAA1549L | c.1866C>T p.H622= (on ENST00000321505; = p.H919= on NM_012194.3) | Silent (SNP) | VAF 90/300 reads (30%) | called by muse, varscan2
- KIF12 | c.1749G>A p.E583= (on ENST00000640217; = p.E445= on NM_138424.1) | Silent (SNP) | VAF 84/351 reads (24%) | called by muse, mutect2, varscan2
- KIF13A | c.1303C>T p.L435= | Silent (SNP) | VAF 63/547 reads (12%) | called by muse, mutect2, varscan2
- KLK2 | c.228T>C p.G76= | Silent (SNP) | VAF 13/269 reads (5%) | called by muse, mutect2
- KMT2D | c.4485C>T p.Y1495= | Silent (SNP) | VAF 79/362 reads (22%) | catalogued as COSV56474587, COSV56475240; called by muse, mutect2, varscan2
- LAG3 | c.681C>T p.F227= | Silent (SNP) | VAF 204/509 reads (40%) | called by muse, mutect2, varscan2
- LDLRAD4 | c.631C>A p.R211= | Silent (SNP) | VAF 190/292 reads (65%) | catalogued as rs770553486, COSV63334286; called by mutect2, varscan2
- LENEP | c.45C>T p.F15= | Silent (SNP) | VAF 353/564 reads (63%) | catalogued as COSV99422443; called by muse, mutect2, varscan2
- LGI2 | c.1305C>T p.S435= | Silent (SNP) | VAF 204/410 reads (50%) | called by muse, mutect2, varscan2
- LHFPL4 | c.294C>T p.F98= | Silent (SNP) | VAF 206/399 reads (52%) | catalogued as rs1271031898, COSV55001038; called by muse, mutect2, varscan2
- LIPN | c.1047C>T p.P349= | Silent (SNP) | VAF 136/225 reads (60%) | catalogued as rs1440299703; called by muse, mutect2, varscan2
- LRRC15 | c.270G>C p.S90= | Silent (SNP) | VAF 36/378 reads (10%) | catalogued as rs1203638096; called by muse, mutect2
- LRRC7 | c.3705G>A p.R1235= (on ENST00000651989 / NM_001370785.2; = p.R1202= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 34/207 reads (16%) | catalogued as COSV50658022; called by muse, mutect2, varscan2
- LRRN2 | c.1434C>T p.P478= | Silent (SNP) | VAF 87/616 reads (14%) | catalogued as rs745814419; called by muse, mutect2, varscan2
- MAB21L4 | c.765G>A p.T255= (on ENST00000388934 / NM_001085437.3; = p.T87= on NM_024861.4) | Silent (SNP) | VAF 82/258 reads (32%) | called by muse, mutect2, varscan2
- MBL2 | c.90G>A p.K30= | Silent (SNP) | VAF 183/278 reads (66%) | called by muse, mutect2, varscan2
- MGAM | c.3138G>A p.K1046= | Silent (SNP) | VAF 61/487 reads (13%) | catalogued as COSV72074094; called by muse, mutect2, varscan2
- MGAT3 | c.654C>T p.F218= | Silent (SNP) | VAF 209/520 reads (40%) | catalogued as rs867840954, COSV100362029, COSV57867867; called by muse, mutect2, varscan2
- MIOX | c.756C>T p.F252= | Silent (SNP) | VAF 99/287 reads (34%) | catalogued as rs562806959, COSV53312169; called by muse, mutect2, varscan2
- MRGPRX1 | c.186C>T p.S62= | Silent (SNP) | VAF 117/342 reads (34%) | catalogued as rs767153444; called by muse, mutect2, varscan2
- MXRA5 | c.7527G>A p.R2509= | Silent (SNP) | VAF 65/370 reads (18%) | catalogued as COSV99479843; called by muse, mutect2
- MXRA5 | c.417C>T p.I139= | Silent (SNP) | VAF 194/551 reads (35%) | catalogued as rs748320635; called by muse, mutect2, varscan2
- MYH2 | c.4740G>A p.R1580= | Silent (SNP) | VAF 106/261 reads (41%) | catalogued as COSV55431125; called by muse, mutect2, varscan2
- MYH8 | c.873G>A p.Q291= | Silent (SNP) | VAF 87/182 reads (48%) | called by muse, mutect2, varscan2
- MYT1L | c.2577C>T p.T859= | Silent (SNP) | VAF 69/235 reads (29%) | called by muse, mutect2, varscan2
- MZT2B | c.378C>T p.S126= | Silent (SNP) | VAF 124/379 reads (33%) | called by muse, mutect2
- NCAN | c.1866C>T p.F622= | Silent (SNP) | VAF 224/442 reads (51%) | catalogued as COSV53046448; called by muse, mutect2, varscan2
- NETO1 | c.1125G>A p.R375= | Silent (SNP) | VAF 121/204 reads (59%) | catalogued as COSV55004452; called by muse, mutect2, varscan2
- NEUROD6 | c.456C>T p.I152= | Silent (SNP) | VAF 63/396 reads (16%) | catalogued as rs533417088, COSV51771941; called by muse, mutect2, varscan2
- NEXMIF | c.2634C>T p.F878= | Silent (SNP) | VAF 184/494 reads (37%) | called by muse, mutect2, varscan2
- NFIC | c.1089C>T p.I363= | Silent (SNP) | VAF 113/243 reads (47%) | catalogued as rs267605402; called by muse, mutect2, varscan2
- NIBAN1 | c.2202G>A p.T734= | Silent (SNP) | VAF 374/554 reads (68%) | catalogued as rs536032437, COSV62286680; called by muse, mutect2, varscan2
- NLRP2 | c.498G>A p.T166= | Silent (SNP) | VAF 100/409 reads (24%) | catalogued as rs755123098, COSV54760573; called by muse, mutect2, varscan2
- NOS2 | c.2565G>A p.E855= | Silent (SNP) | VAF 148/336 reads (44%) | called by muse, mutect2, varscan2
- NPAS4 | c.1692G>A p.Q564= | Silent (SNP) | VAF 83/287 reads (29%) | called by muse, mutect2, varscan2
- NPHP4 | c.3738C>T p.T1246= | Silent (SNP) | VAF 87/436 reads (20%) | catalogued as rs1174471616; called by muse, mutect2, varscan2
- NRK | c.3897G>A p.L1299= | Silent (SNP) | VAF 123/389 reads (32%) | called by muse, mutect2, varscan2
- NWD1 | c.1809C>T p.S603= | Silent (SNP) | VAF 91/353 reads (26%) | called by muse, mutect2, varscan2
- OR12D3 | c.909C>T p.I303= | Silent (SNP) | VAF 77/635 reads (12%) | catalogued as COSV65826281; called by muse, mutect2, varscan2
- OR1G1 | c.9G>A p.G3= | Silent (SNP) | VAF 35/186 reads (19%) | catalogued as COSV61030208; called by muse, mutect2, varscan2
- OR2A1 | c.336C>T p.L112= | Silent (SNP) | VAF 225/597 reads (38%) | catalogued as rs1382409275; called by muse, mutect2, varscan2
- OR2G2 | c.780C>T p.F260= | Silent (SNP) | VAF 331/523 reads (63%) | catalogued as COSV60741210; called by muse, mutect2, varscan2
- OR2M5 | c.309C>T p.F103= | Silent (SNP) | VAF 296/468 reads (63%) | catalogued as rs766652712; called by muse, mutect2, varscan2
- OR4B1 | c.552G>A p.K184= | Silent (SNP) | VAF 81/256 reads (32%) | catalogued as rs763879516; called by muse, mutect2, varscan2
- OR4Q2 | c.546C>T p.P182= | Silent (SNP) | VAF 48/218 reads (22%) | catalogued as rs1270544536; called by muse, mutect2, varscan2
- OR4X2 | c.456C>T p.I152= | Silent (SNP) | VAF 70/275 reads (25%) | catalogued as COSV56582469; called by muse, mutect2, varscan2
- OR56A3 | c.54G>A p.L18= | Silent (SNP) | VAF 70/235 reads (30%) | called by muse, mutect2, varscan2
- OR5B2 | c.387C>T p.H129= | Silent (SNP) | VAF 69/240 reads (29%) | called by muse, mutect2, varscan2
- OR9Q1 | c.594G>A p.L198= | Silent (SNP) | VAF 74/242 reads (31%) | called by muse, mutect2, varscan2
- OTOG | c.5820G>A p.E1940= | Silent (SNP) | VAF 92/336 reads (27%) | called by muse, mutect2, varscan2
- OTOG | c.7611C>T p.S2537= | Silent (SNP) | VAF 45/187 reads (24%) | called by muse, mutect2, varscan2
- OVCH1 | c.3351G>A p.R1117= | Silent (SNP) | VAF 120/268 reads (45%) | called by muse, mutect2, varscan2
- P2RX3 | c.207C>T p.L69= | Silent (SNP) | VAF 103/301 reads (34%) | catalogued as rs1412683008; called by muse, mutect2, varscan2
- PBXIP1 | c.846C>T p.I282= | Silent (SNP) | VAF 362/578 reads (63%) | called by muse, mutect2, varscan2
- PCDHA6 | c.987C>T p.P329= | Silent (SNP) | VAF 51/234 reads (22%) | called by muse, varscan2
- PHRF1 | c.3267C>T p.S1089= (on ENST00000264555 / NM_001286581.2; = p.S1088= on NM_020901.4) | Silent (SNP) | VAF 107/363 reads (29%) | called by muse, mutect2, varscan2
- PIGL | c.690C>T p.L230= | Silent (SNP) | VAF 84/367 reads (23%) | catalogued as rs1382843688; called by muse, mutect2, varscan2
- PIGQ | c.816G>A p.L272= | Silent (SNP) | VAF 218/480 reads (45%) | called by muse, mutect2, varscan2
- PLXNA2 | c.3765C>T p.I1255= | Silent (SNP) | VAF 307/510 reads (60%) | catalogued as rs139061737; called by muse, mutect2, varscan2
- POLR1F | c.903T>C p.G301= | Silent (SNP) | VAF 286/455 reads (63%) | catalogued as COSV55998706; called by muse, mutect2, varscan2
- PON3 | c.345G>A p.G115= | Silent (SNP) | VAF 40/253 reads (16%) | catalogued as rs747574636, COSV99672649; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2310T>A p.T770= | Silent (SNP) | VAF 134/480 reads (28%) | called by muse, mutect2, varscan2
- PPARGC1A | c.2367G>A p.L789= | Silent (SNP) | VAF 99/226 reads (44%) | called by muse, mutect2, varscan2
- PRAMEF1 | c.834C>T p.T278= | Silent (SNP) | VAF 126/298 reads (42%) | catalogued as rs1364522716; called by muse, mutect2
- PRAMEF14 | c.420G>A p.R140= | Silent (SNP) | VAF 168/355 reads (47%) | called by muse, mutect2, varscan2
- PRDM14 | c.612C>T p.F204= | Silent (SNP) | VAF 191/516 reads (37%) | catalogued as rs369845893; called by muse, mutect2, varscan2
- PSG5 | c.786C>T p.F262= | Silent (SNP) | VAF 93/331 reads (28%) | catalogued as rs766162680, COSV61654412; called by muse, mutect2, varscan2
- PTCH2 | c.555C>T p.I185= | Silent (SNP) | VAF 49/301 reads (16%) | catalogued as rs1329291766; called by muse, mutect2, varscan2
- PTCHD4 | c.2430C>T p.F810= | Silent (SNP) | VAF 70/273 reads (26%) | catalogued as COSV100259647, COSV100262138, COSV59791038; called by muse, varscan2
- PTPRN | c.1311A>G p.R437= | Silent (SNP) | VAF 110/351 reads (31%) | called by muse, mutect2, varscan2
- PTPRN2 | c.1806C>T p.F602= | Silent (SNP) | VAF 60/391 reads (15%) | called by muse, mutect2, varscan2
- RASGRP3 | c.1266G>A p.R422= (on ENST00000402538 / NM_001349975.2; = p.R421= on NM_015376.2 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 49/173 reads (28%) | catalogued as rs1169159347, COSV67820408, COSV67826026; called by muse, mutect2, varscan2
- RASSF3 | c.255G>A p.P85= | Silent (SNP) | VAF 133/288 reads (46%) | called by muse, mutect2, varscan2
- RFX6 | c.1851C>T p.F617= | Silent (SNP) | VAF 53/246 reads (22%) | catalogued as rs903661063; called by muse, mutect2, varscan2
- RIC3 | c.420G>A p.R140= | Silent (SNP) | VAF 66/218 reads (30%) | catalogued as COSV58304220; called by muse, mutect2, varscan2
- RNASE1 | c.420G>A p.G140= | Silent (SNP) | VAF 72/373 reads (19%) | catalogued as rs1299487427; called by muse, mutect2, varscan2
- RPGR | c.2604G>A p.K868= (on ENST00000339363 / NM_001367249.1; = p.K663= on NM_000328.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 149/417 reads (36%) | called by muse, mutect2, varscan2
- RXFP3 | c.714G>A p.T238= | Silent (SNP) | VAF 81/383 reads (21%) | catalogued as rs547132118, COSV57508081; called by muse, mutect2, varscan2
- SALL1 | c.3768G>A p.Q1256= | Silent (SNP) | VAF 168/360 reads (47%) | catalogued as rs886052081, COSV99175150; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAPCD1 | c.246C>T p.A82= | Silent (SNP) | VAF 182/722 reads (25%) | called by muse, mutect2, varscan2
- SATB1 | c.1986C>T p.F662= | Silent (SNP) | VAF 92/339 reads (27%) | called by muse, mutect2, varscan2
- SDE2 | c.852C>T p.I284= | Silent (SNP) | VAF 64/336 reads (19%) | catalogued as COSV55250810; called by muse, mutect2, varscan2
- SEMA3C | c.345T>C p.F115= | Silent (SNP) | VAF 182/301 reads (60%) | called by muse, mutect2, varscan2
- SIRPD | c.537C>T p.F179= | Silent (SNP) | VAF 150/397 reads (38%) | catalogued as rs758873532, COSV67547225; called by muse, mutect2, varscan2
- SKIV2L | c.1644A>C p.A548= | Silent (SNP) | VAF 553/769 reads (72%) | called by muse, mutect2, varscan2
- SLC12A6 | c.2400C>T p.F800= (on ENST00000354181 / NM_001365088.1; = p.F749= on NM_005135.2) | Silent (SNP) | VAF 136/344 reads (40%) | called by muse, mutect2, varscan2
- SLC17A2 | c.138G>A p.V46= | Silent (SNP) | VAF 76/791 reads (10%) | catalogued as COSV55354224; called by muse, mutect2
- SLC17A9 | c.531C>T p.L177= | Silent (SNP) | VAF 109/284 reads (38%) | called by muse, mutect2, varscan2
- SLC25A4 | c.726C>T p.S242= | Silent (SNP) | VAF 87/195 reads (45%) | catalogued as rs760995481; called by muse, mutect2, varscan2
- SLC27A1 | c.375C>T p.F125= | Silent (SNP) | VAF 138/532 reads (26%) | catalogued as rs1479473329; called by muse, mutect2, varscan2
- SLC35A4 | c.969C>T p.S323= | Silent (SNP) | VAF 39/172 reads (23%) | called by muse, mutect2, varscan2
- SLC52A3 | c.906C>T p.F302= | Silent (SNP) | VAF 232/648 reads (36%) | called by muse, mutect2
- SLC6A11 | c.195G>A p.G65= | Silent (SNP) | VAF 85/401 reads (21%) | called by muse, mutect2, varscan2
- SLC9A3R1 | c.468C>T p.T156= | Silent (SNP) | VAF 139/337 reads (41%) | called by muse, mutect2, varscan2
- SMTN | c.1233C>T p.P411= | Silent (SNP) | VAF 225/617 reads (36%) | catalogued as COSV60777767; called by muse, mutect2, varscan2
- SNTG1 | c.837T>G p.P279= | Silent (SNP) | VAF 54/201 reads (27%) | catalogued as rs1372247451; called by muse, mutect2, varscan2
- SOGA1 | c.2757C>T p.F919= | Silent (SNP) | VAF 161/406 reads (40%) | catalogued as rs368233695; called by muse, mutect2, varscan2
- SPATA3 | c.528G>A p.R176= | Silent (SNP) | VAF 100/284 reads (35%) | called by muse, mutect2, varscan2
- SPI1 | c.252C>T p.L84= | Silent (SNP) | VAF 125/382 reads (33%) | called by muse, mutect2, varscan2
- SPSB3 | c.556C>T p.L186= | Silent (SNP) | VAF 79/313 reads (25%) | catalogued as COSV99236561; called by muse, mutect2, varscan2
- SSC5D | c.1098C>T p.I366= | Silent (SNP) | VAF 162/351 reads (46%) | called by muse, mutect2, varscan2
- TAAR2 | c.315G>A p.V105= (on ENST00000367931 / NM_001033080.1; = p.V60= on NM_014626.3) | Silent (SNP) | VAF 71/314 reads (23%) | called by muse, mutect2, varscan2
- TAP2 | c.474C>T p.F158= | Silent (SNP) | VAF 540/768 reads (70%) | called by muse, mutect2, varscan2
- TDGF1 | c.250C>T p.L84= | Silent (SNP) | VAF 57/260 reads (22%) | called by muse, mutect2, varscan2
- TENM1 | c.2922A>C p.P974= | Silent (SNP) | VAF 212/544 reads (39%) | called by muse, mutect2, varscan2
- TEX11 | c.420C>T p.I140= (on ENST00000344304; = p.I125= on NM_031276.3) | Silent (SNP) | VAF 135/332 reads (41%) | catalogued as rs770843069; called by muse, mutect2, varscan2
- TEX13C | c.1089G>A p.V363= | Silent (SNP) | VAF 209/516 reads (41%) | called by muse, mutect2, varscan2
- TLNRD1 | c.580C>T p.L194= | Silent (SNP) | VAF 144/421 reads (34%) | catalogued as rs750944779; called by muse, mutect2, varscan2
- TMEM132C | c.567G>A p.G189= | Silent (SNP) | VAF 110/456 reads (24%) | catalogued as COSV101473896, COSV70661320; called by muse, mutect2, varscan2
- TMEM86B | c.384C>T p.I128= | Silent (SNP) | VAF 245/540 reads (45%) | called by muse, mutect2, varscan2
- TNRC6C | c.4443C>T p.P1481= | Silent (SNP) | VAF 109/487 reads (22%) | catalogued as rs770284980; called by muse, mutect2, varscan2
- TNXB | c.10767C>T p.V3589= (on ENST00000647633; = p.V3342= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 291/413 reads (70%) | called by muse, mutect2, varscan2
- TPTE | c.1236G>A p.R412= (on ENST00000618007 / NM_199261.4; = p.R394= on NM_199259.4) | Silent (SNP) | VAF 73/485 reads (15%) | called by muse, mutect2, varscan2
- TRAV8-2 | c.279C>T p.F93= | Silent (SNP) | VAF 125/303 reads (41%) | called by muse, mutect2, varscan2
- TRIM10 | c.192C>T p.F64= | Silent (SNP) | VAF 598/1211 reads (49%) | called by muse, mutect2, varscan2
- TRIM58 | c.21G>A p.G7= | Silent (SNP) | VAF 292/471 reads (62%) | called by muse, mutect2
- TRIM64 | c.1302C>T p.S434= | Silent (SNP) | VAF 50/135 reads (37%) | called by muse, mutect2, varscan2
- TRIM72 | c.1104C>T p.R368= | Silent (SNP) | VAF 240/467 reads (51%) | called by muse, mutect2, varscan2
- TTN | c.58983C>T p.I19661= (on ENST00000591111; = p.I12237= on NM_003319.4) | Silent (SNP) | VAF 59/226 reads (26%) | catalogued as rs566830548; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.11181C>T p.S3727= (on ENST00000591111; = p.S3681= on NM_003319.4) | Silent (SNP) | VAF 80/226 reads (35%) | catalogued as rs1309972074; called by muse, mutect2, varscan2
- TTN | c.6078C>T p.S2026= (on ENST00000591111; = p.S1980= on NM_003319.4) | Silent (SNP) | VAF 78/238 reads (33%) | called by muse, mutect2, varscan2
- UCN | c.198G>A p.A66= | Silent (SNP) | VAF 115/383 reads (30%) | catalogued as COSV51990086; called by muse, mutect2, varscan2
- UNC79 | c.579C>T p.I193= (on ENST00000393151 / NM_001346218.2; = p.I16= on NM_020818.5) | Silent (SNP) | VAF 137/275 reads (50%) | called by muse, mutect2, varscan2
- USP11 | c.1440C>T p.P480= (on ENST00000218348; = p.P437= on NM_001371072.1) | Silent (SNP) | VAF 271/681 reads (40%) | catalogued as rs748250295; called by muse, mutect2, varscan2
- USP17L7 | c.195G>A p.R65= | Silent (SNP) | VAF 220/838 reads (26%) | called by muse, mutect2, varscan2
- WSCD2 | c.1359C>T p.F453= | Silent (SNP) | VAF 43/210 reads (20%) | catalogued as rs572197817, COSV54582518; called by muse, mutect2, varscan2
- ZBTB8B | c.831G>A p.V277= | Silent (SNP) | VAF 116/462 reads (25%) | called by muse, mutect2, varscan2
- ZFHX4 | c.6721C>T p.L2241= | Silent (SNP) | VAF 166/426 reads (39%) | called by muse, mutect2
- ZNF519 | c.594C>T p.F198= | Silent (SNP) | VAF 80/124 reads (65%) | called by muse, mutect2, varscan2
- ZNF599 | c.699G>A p.G233= | Silent (SNP) | VAF 201/373 reads (54%) | called by muse, mutect2, varscan2
- ZNF610 | c.1359G>A p.E453= | Silent (SNP) | VAF 66/308 reads (21%) | catalogued as COSV58347106; called by muse, mutect2, varscan2
- ZNF74 | c.744C>T p.F248= | Silent (SNP) | VAF 239/644 reads (37%) | catalogued as rs763367647, COSV62623263; called by muse, mutect2, varscan2
- ZNF787 | c.732C>T p.I244= | Silent (SNP) | VAF 130/309 reads (42%) | catalogued as rs1245087537, COSV99555451; called by muse, mutect2, varscan2
- ZNF804B | c.1650G>A p.R550= | Silent (SNP) | VAF 43/307 reads (14%) | catalogued as COSV60831661; called by muse, mutect2, varscan2
- ZNFX1 | c.3891C>T p.G1297= | Silent (SNP) | VAF 139/411 reads (34%) | called by muse, mutect2, varscan2
- ADGRB3 | c.2481-697G>A | Intron (SNP) | VAF 63/193 reads (33%) | called by muse, mutect2, varscan2
- ANK3 | c.12596-423C>T | Intron (SNP) | VAF 149/272 reads (55%) | catalogued as COSV55078316; called by muse, mutect2, varscan2
- ATP8B2 | c.1133+65T>A | Intron (SNP) | VAF 355/529 reads (67%) | called by muse, mutect2, varscan2
- BX682237.1 | chrX:155208945 G>A | 3'Flank (SNP) | VAF 169/406 reads (42%) | called by muse, mutect2, varscan2
- CDH11 | c.1895-607C>T | Intron (SNP) | VAF 71/356 reads (20%) | catalogued as COSV51751389; called by muse, mutect2, varscan2
- DCLK3 | c.-106C>T | 5'UTR (SNP) | VAF 61/293 reads (21%) | called by muse, mutect2, varscan2
- DLX4 | c.284-22A>G | Intron (SNP) | VAF 127/503 reads (25%) | called by muse, mutect2, varscan2
- DNAH5 | c.2259+1570C>T | Intron (SNP) | VAF 36/147 reads (24%) | catalogued as rs1432976722; called by muse, mutect2, varscan2
- FGFR3 | c.*486C>T | 3'UTR (SNP) | VAF 149/283 reads (53%) | called by muse, mutect2, varscan2
- GKN1 | c.-12C>T | 5'UTR (SNP) | VAF 53/225 reads (24%) | catalogued as rs141746794; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-16145G>A | Intron (SNP) | VAF 59/213 reads (28%) | called by muse, mutect2, varscan2
- KLHL1 | c.-36G>A | 5'UTR (SNP) | VAF 79/493 reads (16%) | catalogued as rs896846795; called by muse, mutect2, varscan2
- LCORL | chr4:17875732 G>A | 3'Flank (SNP) | VAF 47/169 reads (28%) | called by muse, mutect2, varscan2
- MAFB | c.*735C>T | 3'UTR (SNP) | VAF 99/225 reads (44%) | catalogued as rs1306168665; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640467 G>A | 3'Flank (SNP) | VAF 184/412 reads (45%) | catalogued as rs369841189; called by muse, mutect2, varscan2
- MEGF11 | c.2711-2908G>A | Intron (SNP) | VAF 101/296 reads (34%) | called by muse, mutect2, varscan2
- MLIP | c.613-12089C>T | Intron (SNP) | VAF 82/275 reads (30%) | called by muse, mutect2, varscan2
- PRR19 | c.601+30C>T | Intron (SNP) | VAF 127/526 reads (24%) | called by muse, mutect2, varscan2
- PSG5 | c.431-2731C>T | Intron (SNP) | VAF 54/253 reads (21%) | catalogued as rs369466057; called by muse, mutect2, varscan2
- TAOK2 | c.656-19C>T | Intron (SNP) | VAF 192/382 reads (50%) | called by muse, mutect2, varscan2
- TNIK | c.123+22407G>A | Intron (SNP) | VAF 70/110 reads (64%) | called by muse, mutect2, varscan2
- TTN | c.10360+3028C>T | Intron (SNP) | VAF 63/185 reads (34%) | catalogued as COSV60211859; called by muse, mutect2, varscan2
- XIRP2 | c.*1466C>T | 3'UTR (SNP) | VAF 57/229 reads (25%) | called by muse, mutect2, varscan2
- ZNF787 | c.79+32C>T | Intron (SNP) | VAF 106/455 reads (23%) | catalogued as rs747944867; called by muse, mutect2, varscan2
- ZNF787 | c.79+31C>T | Intron (SNP) | VAF 108/457 reads (24%) | called by muse, mutect2, varscan2
- ZNF81 | c.*565T>C | 3'UTR (SNP) | VAF 59/136 reads (43%) | called by muse, mutect2, varscan2
